CCDI case PBBPXU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/65c4269c-001e-4fb2-a18d-7389c7954ed5

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (282 days).

Biospecimens (3 samples)
- Sample 0DELJ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DELJX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DELKC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
